Somatic mutation profile of tumor specimen 0DZHVX from CCDI case PBCTTY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.4 years (3,080 days).
Specimen 0DZHVX: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a5fb44c-532a-4360-8cd4-86a27022e497.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZHVE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e7a9570-ac18-4055-84de-3e23a5444b20

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX30 | c.1735C>T p.Q579* (on ENST00000445061 / NM_138615.3; = p.Q540* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 82/205 reads (40%) | catalogued as rs1420481269; called by muse, mutect2, varscan2
- MGAM | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs782042260; called by muse, mutect2, varscan2
- NCAPG2 | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs373650801; called by muse, mutect2
- SLC7A4 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 124/238 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763591085; called by muse, mutect2, varscan2
- ADH1C | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- CD163 | c.2552G>A p.G851D | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2
- DIAPH2 | c.2228T>C p.L743P | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBL | c.158G>C p.G53A | Missense Mutation (SNP) | VAF 34/443 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- FGD6 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.011); called by muse, mutect2
- LMAN1L | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 15/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GK | c.801T>G p.S267= (on ENST00000427190 / NM_001205019.2; = p.S261= on NM_000167.6) | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- NLRP3 | c.969C>T p.A323= | Silent (SNP) | VAF 106/325 reads (33%) | catalogued as rs201255971, COSV100276505, COSV60223821; called by muse, mutect2, varscan2
- DUSP22 | c.436-45G>C | Intron (SNP) | VAF 44/182 reads (24%) | catalogued as rs371345397; called by muse, mutect2, varscan2
- HLA-DOA | c.332-74G>A | Intron (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
